Gene-level copy-number profile of tumor specimen HTMCP-03-06-02097-01B from CGCI case HTMCP-03-06-02097, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 41.8 years (15,280 days).
Specimen HTMCP-03-06-02097-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba783552-1267-45d8-8bb9-3c1ef687a6ef.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02097-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,251 have no estimate.
https://portal.gdc.cancer.gov/files/9632c3ee-2fdc-4d01-8a71-84eb64e3a7ed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 4,323; copy number 2: 43,892; copy number 3: 6,692; copy number 4: 2,879; copy number 5: 443; copy number 6: 17; copy number 7: 9; copy number 8: 18; copy number 10: 3; copy number 12: 1; copy number 13: 9; copy number 15: 9; copy number 17: 1; copy number 18: 3; copy number 19: 4; copy number 20: 1; copy number 25: 1.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:31,704,058–31,721,652, 1 gene (within-gene range 0–1): OSBPL10-AS1.
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–1): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr4:8,949,630–9,388,983, 38 genes: AC073648.1, UNC93B8, AC073648.3, AC073648.2, AC073648.5, AC073648.4, AC108519.1, SNRPCP16, AC073648.7, ENPP7P10, FAM86KP, ALG1L14P, FAM90A26, USP17L10, USP17L11, USP17L12, USP17L13, USP17L14P, USP17L15, USP17L16P, USP17L17, USP17L18, USP17L19, USP17L20, USP17L21, USP17L22, USP17L23, USP17L24, USP17L25, USP17L26, USP17L5, USP17L27, USP17L28, USP17L29, USP17L9P, USP17L30, USP17L6P, AC116655.1.
- chr7:74,843,754–74,913,310, 4 genes (within-gene range 0–2): STAG3L2, PMS2P5, Y_RNA, SPDYE12P.
- chr9:61,642,383–61,642,494, 1 gene: Y_RNA.
- chr9:66,022,661–66,113,085, 5 genes (within-gene range 0–19): GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4.
- chr10:50,305,586–50,686,326, 9 genes (within-gene range 0–2): SGMS1, AC069547.2, AC069547.1, AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP.
- chr16:28,637,654–28,658,682, 1 gene: NPIPB8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 519 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,946,085–53,968,168, 1 gene, copy number 5: LRRC42.
- chr1:143,955,364–144,305,180, 9 genes, copy number 13: FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1.
- chr1:149,937,812–154,628,013, 263 genes, copy number 5 (broad region; genes not listed).
- chr1:154,924,740–155,331,114, 44 genes, copy number 5: PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1.
- chr1:161,314,381–161,470,523, 10 genes, copy number 6: SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P, AL592295.3, AL592295.1, AL592295.2.
- chr1:189,989,570–196,747,504, 51 genes, copy number 5: AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031, AL136456.1, AL357793.1, AL357793.2, RPL23AP22, EEF1A1P14, AL513348.1, RNU6-983P, AL353072.1, LINC01724, KCNT2, MIR4735, CFH.
- chr1:224,114,111–224,193,441, 4 genes, copy number 6: FBXO28, AC092809.3, DEGS1, SNORA72.
- chr1:234,979,647–236,502,915, 43 genes, copy number 5 (within-gene range 4–5): AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23, GGPS1, AL357556.3, AL391994.1, AL357556.1, AL357556.5, TBCE, RPS21P1, B3GALNT2, MTCYBP14, MTND6P14, MTND5P19, MTND4P10, MTND4LP21, MTND3P8, MTCO3P46, GNG4, FO393422.1, AL583844.1, LYST, LDHAP2, LYST-AS1, MIR1537, RNU6-968P, AL139161.1, LINC02768, NID1, Y_RNA, AL122018.1, GPR137B, ERO1B, RNU2-70P, AL450309.1, EDARADD.
- chr1:241,916,123–241,999,098, 4 genes, copy number 5: RPL23AP20, BECN2, CFL1P4, MAP1LC3C.
- chr7:76,521,611–76,541,459, 4 genes, copy number 18–20: AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr9:40,321,299–40,333,460, 2 genes, copy number 10: FAM95B1, BX664727.1.
- chr9:41,292,887–41,355,538, 3 genes, copy number 6–25: MYO5BP1, AL354718.2, CDRT15P6.
- chr9:41,644,438–41,699,072, 6 genes, copy number 5: AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA.
- chr9:61,854,148–62,096,920, 1 gene, copy number 5 (within-gene range 2–5): FAM27C.
- chr9:62,266,319–62,435,199, 9 genes, copy number 15: AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2.
- chr9:62,559,839–62,602,672, 2 genes, copy number 5: CNTNAP3P5, RBPJP7.
- chr9:62,837,139–63,385,117, 16 genes, copy number 5: AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4, BMS1P10, AQP7P1, AL845321.1.
- chr9:64,369,394–64,440,180, 3 genes, copy number 5–6: ANKRD20A4P, RNU6-1193P, SNX18P9.
- chr9:64,488,600–65,285,209, 15 genes, copy number 5–12: GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5.
- chr9:66,082,350–66,179,474, 4 genes, copy number 19: SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P.
- chr10:79,825,902–79,827,602, 1 gene, copy number 5 (within-gene range 2–5): AL135925.1.
- chr11:46,602,861–46,617,909, 1 gene, copy number 5 (within-gene range 3–5): HARBI1.
- chr16:28,700,294–28,701,540, 1 gene, copy number 17 (within-gene range 17–34): CDC37P1.
- chr16:33,140,850–33,622,547, 18 genes, copy number 5–8: ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.5, AC136944.1, AC136944.2, AC136944.4, AC136944.3, AC142384.1.
- chr17:78,146,353–78,166,177, 2 genes, copy number 5: C17orf99, EIF5AP2.
- chr21:8,603,547–8,680,934, 2 genes, copy number 8–10: RPSAP68, CR381572.2.

Autosomal genes at a single copy (total copy number 1): 4,203. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
